Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7306, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7306-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]

Phy Locat [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] has had two episodes of lightheadedness, and on MRI there is a circumscribed lesion of low and high density.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain tumor right side

B: Brain tumor right side

C: Brain, right temporal enhancing, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, and C. Brain, right temporal, excisional biopsies:

1. Mixed oligoastrocytoma, "intermediate".

2. MIB-1 proliferation index: 2%.

See Comment.

COMMENT

In the three specimens there is a glial neoplastic proliferation with an

overall oligodendroglial phenotype with small proliferation centers, but also

with a prominent astrocytic component. Mitotic figures are found with difficulty, and the MIB-1 proliferation index is low at about 2% in the more

active areas. There is no microvascular proliferation or necrosis.

In

specimen C there are some proliferation micro centers, some mitoses, and a few hyalinized vessels.

The neoplasm is interpreted as a mixed oligoastrocytoma with low proliferation

index WHO II/III. The focal proliferating activity may portend an aggressive

behavior. In the specimens examined there are no cellular anaplastic features.

[page 2 of 5]
The findings in the biopsy may be correlated with clinical, imaging, and molecular findings for their final interpretation and patient's follow up.

Electronically Signed Out

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S592, D1S552, D19S219, PLA2G4C

Results-Comments

Test performed on tumor paraffin block and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 3 of 5]
determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

There is reproducible low level amplification of the methylated sequence in the MGMT promoter region. This may be due to overall low percentage of tumor DNA content in the submitted paraffin block.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

[page 4 of 5]
INTRA-OPERATIVE CONSULTATION

A. Brain tumor right side, touch prep and smears: Glioma with abnormal vessels (R/O oligodendroglioma, mixed OA). [REDACTED] Frozen section performed at [REDACTED]

[REDACTED] and results reported to the Physician of [REDACTED]

B. Brain tumor right side, touch prep and smears: Glioma with abnormal vessels (R/O oligodendroglioma, mixed OA). [REDACTED] Requested IOH/blood. Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

Received fresh, two fragments, 0.8 cm. In aggregate. Soft, grayish-pink. In total, A1 and A2.

B.

Received fresh, several fragments, 2.2 cm. Across in aggregate. Soft, glistening, yellowish-grey. In total, B1-B3.

C.

Received fresh, one fragment, 0.3 cm. across. Soft, tannish-white, glistening. In total, C1.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates sparse gliofibrillary background.

Only about 4% of cells over express the p53 protein. With the MIB-1 the proliferation index is up to 2% in the more active areas.

ICD-9(s):

239.6 239.6

Billing Fee Code(s): [REDACTED]

Histo Data

Part A: Brain tumor right side

Taken: [REDACTED] Received: [REDACTED]

[page 5 of 5]
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part B: Brain tumor right side

Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT x 1	1		
MIB1-DA x 1	1		
NeuN x 1	1		
P53DO7 x 1	1		
TPS H/E x 1	1		
H/E x 1	2		

Part C: Brain, right temporal enhancing, excision biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
MIB1-DA x 1	1		
TPS H/E x 1	1		

*** End of Report ***

Source: NCI Genomic Data Commons file 985e3882-8c13-48b2-be24-b269327d4d1a (TCGA-DU-7306.DFE1D2E3-A9C7-4D49-984D-5956EEA6CCF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).